Somatic mutation profile of tumor specimen MP2PRT-PAUBVI-TMP1-A (aliquot MP2PRT-PAUBVI-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUBVI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,413 days).
Specimen MP2PRT-PAUBVI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89e1c630-fc48-446c-83b1-1f1e48c06164.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUBVI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUBVI-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8578a49d-8441-4cef-9526-217a6222b661

The open-access MAF lists 14 somatic variants for this specimen: 14 protein-altering or splice-affecting.
By variant classification: Missense Mutation 13, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 78/293 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GABBR2 | c.2777G>A p.R926H | Missense Mutation (SNP) | VAF 165/401 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs901968471, COSV99412110; called by muse, mutect2, varscan2
- GLI2 | c.3010C>T p.R1004C (on ENST00000361492 / NM_001374353.1; = p.R1021C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 248/726 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as rs777929230; called by muse, mutect2, varscan2
- HCST | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 18/582 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.983); catalogued as rs1221777968; called by muse, mutect2
- LZTR1 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 50/565 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1346699262, COSV53151687; called by muse, mutect2
- MALRD1 | c.2494C>T p.R832C | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.659); catalogued as rs1190561512, COSV66007089; called by muse, mutect2
- MYH1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 72/345 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374097415; called by muse, mutect2, varscan2
- THBS1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 151/363 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs1214476407, COSV99527963; called by muse, mutect2, varscan2
- ALDH3A1 | c.1003A>C p.I335L | Missense Mutation (SNP) | VAF 29/666 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); called by muse, mutect2
- CREBBP | c.2976_2977insACCTGTGC p.P993Tfs*8 | Frame Shift Ins (INS) | VAF 111/420 reads (26%) | called by mutect2, pindel, varscan2
- FLNC | c.5908A>G p.T1970A | Missense Mutation (SNP) | VAF 19/604 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2
- FLT3 | c.1799A>T p.D600V | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INTS1 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 93/276 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- VWA3A | c.2774T>A p.V925E | Missense Mutation (SNP) | VAF 131/322 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
